Somatic mutation profile of tumor specimen TCGA-AX-A05S-01A (aliquot TCGA-AX-A05S-01A-11W-A027-09) from TCGA case TCGA-AX-A05S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.9 years (29,928 days).
Specimen TCGA-AX-A05S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c632e8d3-83c8-4021-a54b-b88f441bbd05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A05S-10A (Blood Derived Normal), aliquot TCGA-AX-A05S-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/695851d1-bb61-4a08-9bc6-7d4219eeaa45

The open-access MAF lists 629 somatic variants for this specimen: 486 protein-altering or splice-affecting, 129 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 129, Frame Shift Del 112, Frame Shift Ins 20, Nonsense Mutation 20, In Frame Del 9, Intron 9, Splice Site 4, Splice Region 3, RNA 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 99/302 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, varscan2
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 68/185 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, mutect2, varscan2
- HPRT1 | c.212dup p.Y72Lfs*2 | Frame Shift Ins (INS) | VAF 29/83 reads (35%) | catalogued as rs786200980; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1347_1367del p.L449_Q455del (on ENST00000521381 / NM_181523.3; = p.L179_Q185del on NM_181504.4) | In Frame Del (DEL) | VAF 17/85 reads (20%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PSEN1 | c.697A>G p.M233V | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs63751287, CM004071, CM014376, CM994067, COSV56192890; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 304/386 reads (79%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, varscan2
- ABCA13 | c.10234G>A p.A3412T | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs748270878, COSV71282618; called by muse, mutect2, varscan2
- ABCA4 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 137/464 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs772735093, CM149336, COSV64670527; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs777439793; called by mutect2, varscan2
- ABCC12 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 4/87 reads (5%) | catalogued as rs1399447036, COSV100252674, COSV60917334; called by muse, mutect2
- ABCC2 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 219/924 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs199528736, COSV64970569; called by muse, mutect2, varscan2
- ABCC6 | c.129C>G p.Y43* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV52740874; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs202098129, COSV68343482; called by muse, mutect2, varscan2
- ACE | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.13); catalogued as rs930786156, COSV52003000; called by muse, mutect2, varscan2
- ACOT11 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs373840425; called by muse, mutect2, varscan2
- ADAD1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs13106730, COSV56641069; called by muse, mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 52/162 reads (32%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAM15 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV55124904; called by muse, mutect2, varscan2
- ADAMTS10 | c.2293del p.Q765Sfs*7 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs782743337; called by mutect2, pindel, varscan2
- ADCY10 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV63238311; called by muse, mutect2, varscan2
- AF196969.1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.13); catalogued as COSV52141276; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- AGO3 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1457091939, COSV55790601; called by muse, mutect2, varscan2
- AGO4 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); catalogued as rs1205447580, COSV64616271; called by muse, varscan2
- AGTPBP1 | c.2268G>A p.M756I (on ENST00000357081 / NM_001330701.2; = p.M716I on NM_015239.2) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV61268005; called by muse, mutect2, varscan2
- AHNAK2 | c.506_507del p.I169Kfs*3 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs1408275670; called by mutect2, pindel, varscan2
- AIMP2 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56149646; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 45/152 reads (30%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP9 | c.7976del p.N2659Mfs*3 (on ENST00000359028; = p.N2635Mfs*3 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/111 reads (36%) | catalogued as rs1250599910; called by mutect2, pindel, varscan2
- AL136295.1 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs367669340; called by muse, mutect2, varscan2
- ALDH6A1 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs1374548013, COSV63245671; called by muse, mutect2, varscan2
- ALOX5AP | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 117/351 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV66857584; called by muse, mutect2, varscan2
- ALPK3 | c.4744G>A p.D1582N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.16); catalogued as rs774656964, COSV51928403; called by muse, mutect2, varscan2
- AMBN | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV59825011; called by muse, mutect2, varscan2
- AMER1 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs1174971100, COSV57653697; called by muse, mutect2, varscan2
- ANKRD30A | c.403G>A p.V135I (on ENST00000611781; = p.V79I on NM_052997.2) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.939); catalogued as rs761357009, COSV64602855; called by muse, mutect2, varscan2
- ANKRD49 | c.258+13del | Splice Region (DEL) | VAF 94/200 reads (47%) | catalogued as rs750258320; called by mutect2, varscan2
- ANKRD55 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61943895; called by muse, mutect2, varscan2
- APBA2 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs773558118, COSV68788181; called by muse, mutect2, varscan2
- APOB | c.7897T>C p.F2633L | Missense Mutation (SNP) | VAF 148/395 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.231); catalogued as COSV51921324, COSV51922778; called by muse, mutect2, varscan2
- APOB | c.5870G>T p.R1957M | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV51921337; called by muse, mutect2, varscan2
- ARAP3 | c.4058C>A p.P1353H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53348240; called by muse, mutect2, varscan2
- ARHGAP32 | c.3952C>T p.P1318S (on ENST00000310343 / NM_001378025.1; = p.P969S on NM_014715.4) | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV59842583; called by muse, mutect2, varscan2
- ARHGEF1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868960086, COSV61526025; called by muse, mutect2, varscan2
- ARHGEF6 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV51687106; called by muse, mutect2, varscan2
- ARID4B | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs144849243; called by muse, mutect2, varscan2
- ARMC9 | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV63019168; called by muse, mutect2, varscan2
- ARPP21 | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV51791109; called by muse, mutect2, varscan2
- ARSH | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754973691, COSV66962456; called by muse, mutect2, varscan2
- ATN1 | c.2660G>C p.S887T | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63110164; called by muse, mutect2, varscan2
- ATP6V0D2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as COSV53412881; called by muse, mutect2, varscan2
- ATRNL1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV61796035, COSV61813253; called by muse, mutect2, varscan2
- B3GALT2 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66463738; called by muse, mutect2, varscan2
- BPHL | c.374T>G p.M125R | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66742889; called by muse, mutect2, varscan2
- BPTF | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.092); catalogued as COSV58830553; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 26/66 reads (39%) | catalogued as rs749043197; called by mutect2, varscan2
- BRIP1 | c.3070G>A p.G1024R | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs147119272, COSV52009457; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- C20orf194 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV52690644; called by muse, mutect2, varscan2
- C5orf15 | c.726A>T p.E242D | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV51547899; called by muse, mutect2, varscan2
- CACNA1E | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62380982; called by muse, mutect2, varscan2
- CAMSAP3 | c.3699G>A p.W1233* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV50330618; called by muse, mutect2, varscan2
- CAMTA1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.041); catalogued as rs768327327, COSV100352303, COSV57879328; called by muse, mutect2, varscan2
- CAPN2 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199728877, COSV99688876; called by muse, mutect2, varscan2
- CARD11 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV62718388; called by muse, mutect2
- CASP10 | c.1371G>A p.W457* (on ENST00000272879 / NM_032974.5; = p.W414* on NM_001230.5) | Nonsense Mutation (SNP) | VAF 82/234 reads (35%) | catalogued as COSV53776427; called by muse, mutect2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 100/300 reads (33%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2, varscan2
- CASZ1 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs764846470, COSV59731132; called by muse, mutect2, varscan2
- CBL | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 211/599 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50629615; called by muse, mutect2, varscan2
- CCDC114 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs757102955, COSV59554952; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC171 | c.2617_2619del p.L873del | In Frame Del (DEL) | VAF 174/576 reads (30%) | catalogued as rs1488751989; called by pindel, varscan2
- CCDC171 | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 194/546 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52633093; called by muse, varscan2
- CCDC89 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as COSV57033447, COSV57033608; called by muse, mutect2, varscan2
- CCN2 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV63466409; called by muse, mutect2, varscan2
- CCNE2 | c.1170_1172del p.I390del | In Frame Del (DEL) | VAF 65/196 reads (33%) | catalogued as rs766405579; called by mutect2, pindel, varscan2
- CD5L | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.962); catalogued as COSV63820951; called by muse, mutect2, varscan2
- CD96 | c.752T>C p.V251A (on ENST00000283285 / NM_198196.3; = p.V235A on NM_005816.5) | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV51912164; called by muse, mutect2, varscan2
- CELSR3 | c.6029G>A p.C2010Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50839463; called by muse, mutect2, varscan2
- CEP290 | c.6927del p.V2310Lfs*37 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs1441877386; called by mutect2, pindel, varscan2
- CEP290 | c.3250C>T p.R1084W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs372918770, COSV58348048; called by muse, mutect2, varscan2
- CFTR | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397508147, CM931146, COSV50040443; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CHI3L1 | c.54C>T p.C18= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as COSV55136924; called by muse, mutect2, varscan2
- CIDEA | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs758298543, COSV57597063; called by muse, mutect2, varscan2
- CNGA1 | c.1091del p.P364Lfs*3 | Frame Shift Del (DEL) | VAF 87/307 reads (28%) | catalogued as rs1428479359, COSV62053715; called by mutect2, pindel, varscan2
- COL11A1 | c.1735del p.R579Gfs*54 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | catalogued as COSV62195334; called by mutect2, pindel, varscan2
- COL7A1 | c.4859G>A p.R1620Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs373682717; called by muse, mutect2
- CPA4 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV99744944; called by muse, mutect2
- CPNE8 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58836947; called by muse, mutect2, varscan2
- CPS1 | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as COSV99242980; called by muse, mutect2
- CPSF3 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs779316073, COSV53007590; called by muse, mutect2, varscan2
- CPT1C | c.780del p.Y261Mfs*26 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as COSV54917266; called by mutect2, pindel, varscan2
- CR2 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs1193574112, COSV100889719, COSV65505871; called by muse, mutect2, varscan2
- CSNK1E | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV63290326; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 53/212 reads (25%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTC1 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768361173, COSV59851770, COSV59854016; called by muse, mutect2, varscan2
- CTNND1 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV62381978; called by muse, mutect2, varscan2
- CYLC2 | c.531A>T p.E177D | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs1178432236, COSV66335842; called by muse, mutect2, varscan2
- CYP4F3 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs148052542; called by muse, mutect2, varscan2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | catalogued as rs1467050790; called by mutect2, pindel, varscan2
- DAAM2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772573007, COSV51301862; called by muse, mutect2, varscan2
- DAP3 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as COSV58018984; called by muse, mutect2, varscan2
- DCAKD | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV60830230; called by muse, mutect2, varscan2
- DCST2 | c.2119_2121del p.E707del | In Frame Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs774601504; called by pindel, varscan2
- DCST2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55049917; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs766714372; called by mutect2, varscan2
- DENND4A | c.4442C>T p.P1481L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101475378, COSV71265132; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs35538077; called by mutect2, pindel
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DMD | c.7295C>T p.T2432I | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV58888696; called by muse, mutect2, varscan2
- DNAH11 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 91/274 reads (33%) | catalogued as rs1228238442, COSV60937043; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 46/142 reads (32%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAI1 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54277961; called by muse, mutect2, varscan2
- DPYSL2 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60781575; called by muse, mutect2, varscan2
- DSG2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as rs754281384, COSV55196413, COSV99853600; called by muse, mutect2, varscan2
- DYNC1H1 | c.13673T>G p.F4558C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64133922; called by muse, mutect2, varscan2
- DYRK1A | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs1470299902, COSV100118232, COSV58292124; called by muse, mutect2, varscan2
- DZIP3 | c.3007del p.L1003* | Frame Shift Del (DEL) | VAF 154/476 reads (32%) | catalogued as rs1559785411; called by mutect2, varscan2
- EDA2R | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV53629931; called by muse, mutect2, varscan2
- EDARADD | c.148G>A p.E50K (on ENST00000334232 / NM_145861.4; = p.E40K on NM_080738.4) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1486308538, COSV62060760; called by muse, mutect2, varscan2
- EFHC1 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1172185919, COSV64135281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFNA1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs1451875266, COSV57596158; called by muse, mutect2, varscan2
- ELAVL2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 89/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56356489; called by muse, mutect2, varscan2
- EPHA10 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.999); catalogued as rs1281039637, COSV57621110; called by muse, mutect2, varscan2
- EPHA8 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs567786868, COSV51262219; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 62/102 reads (61%) | catalogued as rs775950025; called by mutect2, varscan2
- ESS2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs775514047, COSV52815966; called by muse, varscan2
- FAM167A | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs745542182, COSV52667359; called by muse, mutect2, varscan2
- FAM220A | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV57625701; called by muse, mutect2, varscan2
- FAM47A | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs756452001, COSV60493630; called by muse, mutect2, varscan2
- FAM71C | c.408del p.K136Nfs*5 | Frame Shift Del (DEL) | VAF 76/253 reads (30%) | catalogued as rs762930877; called by mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as rs748967872; called by mutect2, varscan2
- FBLN5 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50902006; called by muse, mutect2, varscan2
- FCGR2C | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.636); catalogued as rs1335311228, COSV63434620; called by muse, mutect2, varscan2
- FGD3 | c.1807dup p.Q603Pfs*16 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs769439022; called by mutect2, pindel, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 52/132 reads (39%) | catalogued as rs777372807; called by mutect2, varscan2
- FH | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 104/406 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs147528200; ClinVar: not provided / uncertain significance; called by muse, varscan2
- FIGLA | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1350558167, COSV60088582; called by muse, mutect2, varscan2
- FKBP5 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as rs1238020852, COSV61879506; called by muse, mutect2, varscan2
- FKBP8 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.258); catalogued as rs1341140154, COSV55890907; called by muse, mutect2, varscan2
- FMO4 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 126/457 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as COSV63000532; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs760347049; called by mutect2, pindel
- FRA10AC1 | c.694del p.R232Efs*96 | Frame Shift Del (DEL) | VAF 66/268 reads (25%) | catalogued as rs775948504; called by mutect2, varscan2
- FRMPD1 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV66698946; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 37/120 reads (31%) | catalogued as rs756304971; called by mutect2, varscan2
- FYB2 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs140787553; called by muse, mutect2, varscan2
- GAD1 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs753558119, COSV64024724; called by muse, mutect2, varscan2
- GALNT1 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV52450262; called by muse, mutect2, varscan2
- GALNTL5 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601426, COSV101217812; called by muse, mutect2
- GGA2 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV59167241, COSV59168063; called by muse, mutect2, varscan2
- GNAS | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55670399; called by muse, mutect2, varscan2
- GNB1 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66099658; called by muse, mutect2, varscan2
- GOPC | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV50000017; called by muse, mutect2, varscan2
- GP5 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as COSV55461029; called by muse, mutect2, varscan2
- GPR12 | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67343960; called by muse, mutect2, varscan2
- GPRC5A | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 94/249 reads (38%) | catalogued as rs139366106; called by muse, mutect2, varscan2
- GRPEL2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.921); catalogued as COSV61387188; called by muse, mutect2, varscan2
- GRSF1 | c.716T>C p.L239S | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as COSV99635706; called by muse, mutect2
- GSG1L | c.992T>C p.V331A (on ENST00000447459 / NM_001109763.2; = p.V176A on NM_144675.2) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV66575359; called by muse, mutect2, varscan2
- GSX1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57232316; called by muse, mutect2, varscan2
- GUCY2C | c.2717C>T p.T906I | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs775576196, COSV53786335; called by muse, mutect2, varscan2
- GUK1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV57154699; called by muse, mutect2
- HCN3 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs765497777, COSV61360200; called by muse, mutect2, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 25/64 reads (39%) | catalogued as rs771658394; called by mutect2, varscan2
- HHATL | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.963); catalogued as COSV60040698; called by muse, mutect2, varscan2
- HM13 | c.880A>C p.S294R | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV59435499; called by muse, mutect2, varscan2
- HNF4G | c.112C>T p.R38C (on ENST00000354370 / NM_001330561.2; = p.R85C on NM_004133.5) | Missense Mutation (SNP) | VAF 137/414 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772036366, COSV62965321; called by muse, mutect2, varscan2
- HOOK3 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs1215666193, COSV56878728; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTR7 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53282240; called by muse, mutect2, varscan2
- IARS2 | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.451); catalogued as rs1398523485, COSV56957215; called by muse, mutect2, varscan2
- IDH3G | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54205808; called by muse, mutect2, varscan2
- IGF2BP1 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV51728383; called by muse, mutect2, varscan2
- IL11RA | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV52404485; called by muse, mutect2, varscan2
- IL31RA | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs150630121; called by muse, mutect2
- IMPA2 | c.648_649del p.A218Rfs*63 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs1236905781; called by mutect2, pindel, varscan2
- INTS3 | c.1197G>A p.W399* | Nonsense Mutation (SNP) | VAF 12/366 reads (3%) | catalogued as COSV100015983; called by muse, mutect2
- IRF8 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51896347; called by muse, mutect2, varscan2
- ITGA1 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs755107293, COSV50876236; called by muse, mutect2, varscan2
- ITPR3 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs747839088, COSV65405072; called by muse, mutect2, varscan2
- ITPRID2 | c.1640C>T p.T547M | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285424595, COSV57469130; called by muse, mutect2, varscan2
- KATNIP | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55172478; called by muse, mutect2
- KCMF1 | c.848A>G p.Q283R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV69053061; called by muse, mutect2, varscan2
- KCNA5 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99363875; called by muse, mutect2
- KCTD21 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370613583, COSV60740668; called by muse, mutect2, varscan2
- KDM1A | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779514366, COSV56498087; called by muse, mutect2, varscan2
- KDM5A | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV66990078; called by muse, mutect2, varscan2
- KIAA0232 | c.216C>G p.Y72* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV56923002; called by muse, mutect2, varscan2
- KIAA1109 | c.9509C>A p.T3170N | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52660915; called by muse, mutect2, varscan2
- KIF1B | c.2162G>A p.R721Q (on ENST00000377086 / NM_001365952.1; = p.R675Q on NM_015074.3) | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs763303622, COSV55802713; called by muse, mutect2, varscan2
- KIF27 | c.1090A>G p.K364E | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV99926969, COSV99927277; called by muse, mutect2
- KLRB1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767855289, COSV57589069; called by muse, mutect2, varscan2
- KMO | c.1369T>G p.W457G | Missense Mutation (SNP) | VAF 105/463 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.197); catalogued as COSV59362118; called by muse, mutect2, varscan2
- KRT32 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs762610129, COSV56785320; called by muse, mutect2, varscan2
- KRT6C | c.1550A>G p.Y517C | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); catalogued as rs914748964, COSV52876204; called by muse, mutect2, varscan2
- KRTAP5-6 | c.311G>A p.C104Y | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV66289087; called by muse, mutect2, varscan2
- L3MBTL2 | c.47T>A p.M16K | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV53431422; called by muse, mutect2, varscan2
- LAMA2 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70336986; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 37/174 reads (21%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LBP | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54138390; called by muse, mutect2, varscan2
- LDOC1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782286173, COSV65159075; called by muse, mutect2, varscan2
- LGMN | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs376054031; called by muse, mutect2, varscan2
- LIPE | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018338752, COSV54920924, COSV99734449; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 100/324 reads (31%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LONP2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV53519897; called by muse, mutect2, varscan2
- LSS | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs570157673, COSV62699752; called by muse, mutect2, varscan2
- LTBP1 | c.3827A>G p.Q1276R (on ENST00000404816 / NM_206943.4; = p.Q950R on NM_000627.4) | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV99698268; called by muse, mutect2
- LTN1 | c.3934del p.S1312Pfs*13 | Frame Shift Del (DEL) | VAF 55/201 reads (27%) | catalogued as rs1568836342; called by mutect2, pindel, varscan2
- LY6K | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs782265835, COSV52831894; called by muse, mutect2, varscan2
- MACROH2A1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781076332, COSV56892956; called by muse, varscan2
- MAGEC1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 42/986 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as COSV53572180, COSV99595678; called by muse, mutect2
- MAP3K4 | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as rs772013786, COSV62329815, COSV62334286; called by muse, mutect2, varscan2
- MAP3K7 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV65223429; called by muse, mutect2, varscan2
- MAPK7 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55189087; called by muse, mutect2, varscan2
- MARCHF1 | c.829C>T p.P277S (on ENST00000274056; = p.P260S on NM_017923.4) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as COSV56806907; called by muse, mutect2, varscan2
- MBNL2 | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59117124; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs776473131; called by mutect2, varscan2
- MCU | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 172/712 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as COSV64064520; called by muse, mutect2, varscan2
- MICAL3 | c.3287C>T p.T1096I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV71588016; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as COSV54098507; called by mutect2, pindel, varscan2
- MMP9 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63433677; called by muse, mutect2, varscan2
- MNDA | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63739759; called by muse, mutect2, varscan2
- MPP7 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs148352336; called by muse, mutect2, varscan2
- MRGPRX3 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66933112; called by muse, mutect2, varscan2
- MROH5 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs150372378; called by muse, mutect2, varscan2
- MRPL11 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs775327537, COSV60598263; called by muse, mutect2, varscan2
- MRPS30 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50181463; called by muse, mutect2, varscan2
- MRPS31 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 82/239 reads (34%) | catalogued as rs775319985, COSV60265973; called by muse, mutect2, varscan2
- MST1R | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as rs756120059, COSV56563863; called by muse, mutect2, varscan2
- MTRR | c.1235del p.L412Cfs*157 (on ENST00000264668; = p.L385Cfs*157 on NM_002454.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | catalogued as COSV52945148; called by mutect2, pindel, varscan2
- MUC16 | c.39370T>C p.Y13124H | Missense Mutation (SNP) | VAF 40/1196 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV101109887; called by muse, mutect2
- MYOM1 | c.4558G>A p.E1520K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs755380862, COSV55284715; called by muse, mutect2, varscan2
- MYPN | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV62731205; called by muse, mutect2, varscan2
- MYPN | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 81/270 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140037748, COSV62731212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV2 | c.4919C>T p.S1640F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60656047; called by muse, mutect2, varscan2
- NISCH | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV61898104; called by muse, mutect2, varscan2
- NLGN3 | c.2468C>T p.T823I (on ENST00000358741 / NM_181303.2; = p.T803I on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV62441404; called by muse, mutect2, varscan2
- NOLC1 | c.840dup p.P281Tfs*5 | Frame Shift Ins (INS) | VAF 32/136 reads (24%) | catalogued as rs759637346; called by mutect2, varscan2
- NOTCH3 | c.4999C>T p.R1667C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54625117; called by muse, mutect2, varscan2
- NPFFR2 | c.1372del p.R458Efs*10 | Frame Shift Del (DEL) | VAF 44/185 reads (24%) | catalogued as rs1405220543; called by mutect2, pindel, varscan2
- NSMCE4A | c.295A>C p.N99H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs569424180, COSV64632521; called by muse, mutect2
- NTMT1 | c.626A>T p.N209I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV52964300; called by muse, mutect2, varscan2
- NUDT6 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as COSV58644970; called by muse, mutect2, varscan2
- NUP93 | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV57428176; called by muse, mutect2, varscan2
- OGDH | c.2726A>G p.Y909C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56044875; called by muse, mutect2, varscan2
- OR10H2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs756001079, COSV59945286; called by muse, mutect2, varscan2
- OR5D13 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV62332570; called by muse, mutect2, varscan2
- OR5H15 | c.580A>G p.I194V | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.26); catalogued as rs779437662, COSV62947258; called by muse, mutect2, varscan2
- OR6C3 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 150/474 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV65570529; called by muse, varscan2
- PANK3 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs372745752; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | catalogued as rs758945932; called by mutect2, varscan2
- PAXIP1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68184567; called by muse, mutect2, varscan2
- PBDC1 | c.233A>T p.N78I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV64895537; called by muse, mutect2, varscan2
- PCDH15 | c.4961T>C p.L1654S (on ENST00000644397 / NM_001354429.2; = p.L1596S on NM_001142771.2) | Missense Mutation (SNP) | VAF 197/840 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV64670154; called by muse, mutect2, varscan2
- PCDHA6 | c.1910T>C p.L637P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV65341450; called by muse, mutect2, varscan2
- PCDHB9 | c.1176del p.L393* | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | catalogued as rs782200278; called by mutect2, pindel, varscan2
- PCGF3 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62858139; called by muse, mutect2, varscan2
- PCNX4 | c.2654C>T p.A885V (on ENST00000406854 / NM_001330177.2; = p.A651V on NM_022495.5) | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58302051; called by muse, mutect2, varscan2
- PDCD11 | c.3008T>C p.M1003T | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1365100829, COSV63932864; called by muse, mutect2, varscan2
- PDCD11 | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV63932868; called by muse, mutect2, varscan2
- PDCD5 | c.294del p.V99* | Frame Shift Del (DEL) | VAF 54/179 reads (30%) | catalogued as rs1373819281; called by mutect2, pindel, varscan2
- PEG10 | c.752G>A p.R251H (on ENST00000482108 / NM_001040152.2; = p.R285H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.375); catalogued as COSV71787921; called by muse, mutect2, varscan2
- PEX12 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV99862149; called by muse, mutect2
- PFKP | c.2038C>G p.P680A | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV56525114; called by muse, mutect2, varscan2
- PHC3 | c.2926C>T p.R976C (on ENST00000494943 / NM_001308116.2; = p.R988C on NM_024947.4) | Missense Mutation (SNP) | VAF 138/417 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs373572852; called by muse, mutect2, varscan2
- PI15 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 139/557 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs933277228, COSV52639325; called by muse, mutect2, varscan2
- PI4KA | c.6017G>T p.G2006V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55402777; called by muse, mutect2, varscan2
- PIP5K1A | c.1411C>T p.R471W (on ENST00000368888 / NM_001135638.2; = p.R458W on NM_003557.3) | Missense Mutation (SNP) | VAF 112/533 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.586); catalogued as rs1360030623, COSV62957228; called by muse, mutect2, varscan2
- PLXNA1 | c.4304C>T p.S1435L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs1364747851, COSV52521643; called by muse, mutect2
- PLXNA1 | c.4988T>C p.L1663P | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV52521649; called by muse, varscan2
- POF1B | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs755105978, COSV53129786; called by muse, mutect2, varscan2
- POFUT2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs560306914, COSV57957530; called by muse, mutect2, varscan2
- POLD3 | c.890A>G p.E297G | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as rs375954131, COSV55240660; called by mutect2, varscan2
- POMC | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as COSV53034290; called by muse, mutect2
- POU3F4 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1421127773, COSV64537552; called by muse, mutect2, varscan2
- PPRC1 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53382731; called by muse, mutect2, varscan2
- PPT1 | c.826G>A p.A276T (on ENST00000433473; = p.A277T on NM_000310.4) | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV61222652; called by muse, mutect2, varscan2
- PRAMEF14 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1399633588; called by muse, mutect2, varscan2
- PRKCI | c.826del p.T276Qfs*7 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs753143066; called by mutect2, varscan2
- PRPF40B | c.410G>A p.C137Y (on ENST00000380281; = p.C131Y on NM_012272.3) | Missense Mutation (SNP) | VAF 139/390 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1393769320, COSV56057451; called by muse, mutect2, varscan2
- PRRC2A | c.5851C>T p.P1951S | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.3); catalogued as COSV52987514; called by muse, mutect2, varscan2
- PRRC2C | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58900079; called by muse, mutect2, varscan2
- PTCHD3 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs757522719, COSV71256241; called by muse, mutect2, varscan2
- PTTG1 | c.491del p.P164Lfs*4 | Frame Shift Del (DEL) | VAF 47/134 reads (35%) | catalogued as rs1042131472; called by mutect2, pindel, varscan2
- PXDN | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as rs973423334, COSV53225467; called by muse, mutect2, varscan2
- QKI | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV51688694; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RAB3C | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.668); catalogued as rs140644565; called by muse, mutect2, varscan2
- RABGGTB | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200085575, COSV60636724; called by muse, mutect2, varscan2
- RABL6 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757581080, COSV61032786; called by muse, mutect2, varscan2
- RANBP6 | c.2918dup p.N973Kfs*19 | Frame Shift Ins (INS) | VAF 31/91 reads (34%) | catalogued as rs746880803; called by mutect2, varscan2
- RAP2A | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV55354132; called by muse, mutect2, varscan2
- RASGRF2 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54122102; called by muse, mutect2, varscan2
- RBM10 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV61307528; called by muse, mutect2, varscan2
- RBM17 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65913583; called by muse, mutect2, varscan2
- RBM25 | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.899); catalogued as COSV99998693; called by muse, mutect2
- RBM47 | c.1283A>T p.N428I | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as COSV55929636; called by muse, mutect2, varscan2
- RESF1 | c.4877A>T p.N1626I | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57019258; called by muse, mutect2, varscan2
- REST | c.2370G>T p.K790N | Missense Mutation (SNP) | VAF 113/368 reads (31%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.021); catalogued as COSV58359128; called by muse, mutect2, varscan2
- RGN | c.113dup p.V39Gfs*57 | Frame Shift Ins (INS) | VAF 47/169 reads (28%) | catalogued as rs782518957; called by mutect2, pindel, varscan2
- RMND1 | c.856del p.E286Kfs*4 | Frame Shift Del (DEL) | VAF 56/217 reads (26%) | catalogued as COSV60550439, COSV60551671; called by mutect2, pindel, varscan2
- RNF213 | c.13940G>A p.R4647H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs767758584, COSV60388624; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS27L | c.57_58del p.H19Qfs*61 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs778278352; called by mutect2, pindel, varscan2
- RPS6KA2 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs200077411; called by muse, mutect2, varscan2
- RRH | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 283/806 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs566521268, COSV58490461; called by muse, mutect2, varscan2
- SAMD9L | c.3562C>T p.R1188* | Nonsense Mutation (SNP) | VAF 331/950 reads (35%) | catalogued as rs572865269, COSV59079092; called by muse, mutect2, varscan2
- SCAF1 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs767108871, COSV55868075; called by muse, mutect2, varscan2
- SDHA | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.099); catalogued as rs878854629, COSV53765094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67354590; called by muse, mutect2
- SEC14L1 | c.439del p.I147Lfs*3 | Frame Shift Del (DEL) | VAF 35/111 reads (32%) | catalogued as rs34381783; called by mutect2, pindel, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEC24B | c.1783C>G p.P595A | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs753747307, COSV54494881; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 40/84 reads (48%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEPTIN9 | c.134G>A p.R45Q (on ENST00000427177 / NM_001113491.2; = p.R27Q on NM_006640.4) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781163314, COSV61201747, COSV61203636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD1A | c.2123G>C p.G708A | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.009); catalogued as rs1373477376, COSV52684573, COSV99353832; called by muse, mutect2, varscan2
- SEZ6 | c.2402A>G p.Q801R | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV57976817; called by muse, mutect2, varscan2
- SEZ6L2 | c.1237C>A p.L413I (on ENST00000308713 / NM_001114099.3; = p.L343I on NM_012410.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV58096751; called by muse, mutect2, varscan2
- SFMBT1 | c.1034T>C p.I345T | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV56251490; called by muse, mutect2, varscan2
- SGK1 | c.1100_1102del p.K367del | In Frame Del (DEL) | VAF 86/253 reads (34%) | catalogued as rs1562235584; called by pindel, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 35/102 reads (34%) | catalogued as rs747473028; called by mutect2, varscan2
- SH2D7 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as rs569631963, COSV60925802; called by muse, mutect2, varscan2
- SHCBP1 | c.1797T>A p.C599* | Nonsense Mutation (SNP) | VAF 149/456 reads (33%) | catalogued as COSV57646185; called by muse, mutect2, varscan2
- SHPRH | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574465156, COSV51604046, COSV99261771; called by muse, mutect2, varscan2
- SIMC1 | c.1034C>T p.P345L (on ENST00000443967 / NM_001308196.1; = p.P364L on NM_001308195.2) | Missense Mutation (SNP) | VAF 65/868 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV100365484; called by muse, mutect2
- SLC10A2 | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV55356778, COSV55360845; called by muse, mutect2, varscan2
- SLC1A6 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55667458; called by muse, mutect2, varscan2
- SLC22A9 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 130/378 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs1181936910, COSV54165262; called by muse, varscan2
- SLC30A9 | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.019); catalogued as COSV52553632; called by muse, mutect2, varscan2
- SLC38A10 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs772492283, COSV55842269; called by muse, mutect2, varscan2
- SLC39A6 | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52367586; called by muse, mutect2, varscan2
- SLC6A2 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.449); catalogued as rs148722045; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | catalogued as rs754697669; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 30/111 reads (27%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 66/208 reads (32%) | catalogued as rs760667210; called by mutect2, varscan2
- SMG1 | c.7892G>A p.R2631H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs541077689, COSV101245700, COSV67169154; called by muse, mutect2, varscan2
- SMOX | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749058005, COSV53862574; called by muse, mutect2, varscan2
- SNX17 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs781527109, COSV52006117; called by muse, mutect2, varscan2
- SNX25 | c.1838A>G p.Q613R | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV53011036; called by muse, mutect2, varscan2
- SOAT1 | c.1330T>A p.F444I | Missense Mutation (SNP) | VAF 77/319 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV62652308; called by muse, mutect2, varscan2
- SON | c.5186A>G p.N1729S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV51649108; called by muse, mutect2, varscan2
- SORCS1 | c.3112C>T p.P1038S | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV53838196; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 66/202 reads (33%) | catalogued as rs1278336874; called by mutect2, varscan2
- SPAG16 | c.340T>C p.C114R | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.991); catalogued as COSV55982937; called by muse, mutect2, varscan2
- SPATA31D1 | c.1077G>A p.W359* | Nonsense Mutation (SNP) | VAF 20/426 reads (5%) | catalogued as COSV100782768; called by muse, mutect2
- SPATS2L | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs762723752, COSV62344860; called by muse, mutect2, varscan2
- SPTBN2 | c.4945G>A p.A1649T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.309); catalogued as COSV59445831; called by muse, mutect2, varscan2
- SRRM4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs375268699; called by muse, mutect2, varscan2
- SSB | c.578dup p.N193Kfs*2 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs753297385; called by mutect2, varscan2
- ST3GAL1 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | PolyPhen probably damaging (1); catalogued as COSV60610193; called by muse, mutect2, varscan2
- ST6GAL2 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV64525770; called by muse, mutect2, varscan2
- STAP2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55694266; called by muse, mutect2, varscan2
- STRA6 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV60584222; called by muse, mutect2, varscan2
- SUCO | c.628G>T p.G210* | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as COSV55261358; called by muse, mutect2, varscan2
- SULT1B1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371978235, COSV60206548, COSV60209064; called by muse, mutect2, varscan2
- SUPT6H | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV58924138; called by muse, mutect2, varscan2
- SUSD2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); catalogued as rs1217339809, COSV64202626; called by muse, mutect2, varscan2
- SYNPO | c.842T>C p.L281P (on ENST00000394243 / NM_001166208.2; = p.L37P on NM_007286.6) | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56937841; called by muse, mutect2, varscan2
- SYNPR | c.133T>A p.F45I | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV55721791; called by muse, mutect2, varscan2
- TAF1 | c.5484C>A p.H1828Q (on ENST00000373790 / NM_138923.4; = p.H1849Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV52106235; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D9 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV71306708; called by muse, mutect2, varscan2
- TCERG1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs369012572; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 66/259 reads (25%) | catalogued as rs758822980; called by mutect2, varscan2
- TEKT3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV58625709; called by muse, mutect2, varscan2
- TEX15 | c.7972T>C p.Y2658H (on ENST00000256246; = p.Y3041H on NM_001350162.2) | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV56340962; called by muse, mutect2, varscan2
- TGM4 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs145695632; called by muse, mutect2, varscan2
- THOC2 | c.3037A>G p.T1013A | Missense Mutation (SNP) | VAF 152/441 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55539448; called by muse, mutect2, varscan2
- TJAP1 | c.1219G>A p.E407K (on ENST00000372445 / NM_001146016.1; = p.E397K on NM_080604.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1350529714, COSV52499027; called by muse, mutect2, varscan2
- TKFC | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV53650701; called by muse, mutect2, varscan2
- TMEM132E | c.1480C>T p.R494C (on ENST00000321639; = p.R584C on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140959400, COSV100396039; called by muse, mutect2, varscan2
- TMEM167B | c.142+1G>A p.X48_splice | Splice Site (SNP) | VAF 120/270 reads (44%) | catalogued as COSV57807784; called by muse, mutect2, varscan2
- TMEM229B | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); catalogued as COSV62538335; called by muse, mutect2
- TMEM237 | c.550del p.S184Afs*12 (on ENST00000409883 / NM_001044385.3; = p.S176Afs*12 on NM_152388.4) | Frame Shift Del (DEL) | VAF 62/203 reads (31%) | catalogued as rs1234599681; called by mutect2, pindel, varscan2
- TNRC6B | c.5387del p.P1796Qfs*59 (on ENST00000454349 / NM_001162501.2; = p.P1686Qfs*59 on NM_015088.3) | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as COSV100110716; called by mutect2, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TPD52 | c.215C>T p.S72L (on ENST00000379097 / NM_001025252.3; = p.S32L on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/339 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs150326619; called by muse, mutect2, varscan2
- TRANK1 | c.2885G>A p.R962K | Missense Mutation (SNP) | VAF 151/427 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57139116; called by muse, mutect2, varscan2
- TRMT13 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs754518148, COSV61582589; called by muse, mutect2, varscan2
- TTC3 | c.2310dup p.L771Ifs*26 | Frame Shift Ins (INS) | VAF 83/257 reads (32%) | catalogued as rs1227714276; called by mutect2, pindel, varscan2
- TTLL5 | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 127/332 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV53168551; called by muse, varscan2
- TTN | c.90617G>A p.R30206H (on ENST00000591111; = p.R22782H on NM_003319.4) | Missense Mutation (SNP) | VAF 192/545 reads (35%) | PolyPhen probably damaging (0.998); catalogued as rs771179752, COSV59861705; called by muse, mutect2, varscan2
- TUT1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765973002, COSV53468504; called by muse, mutect2, varscan2
- UBR4 | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.076); catalogued as COSV64382058; called by muse, mutect2, varscan2
- UFL1 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs768541388, COSV65149206; called by muse, mutect2, varscan2
- UNC45B | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs752587517, COSV52091640; called by muse, mutect2, varscan2
- UNC5B | c.1804A>G p.S602G | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV58973886; called by muse, mutect2, varscan2
- USE1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201641941, COSV55726588; called by muse, mutect2, varscan2
- USP20 | c.1834C>A p.L612M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.354); catalogued as rs762777991, COSV59610615; called by muse, mutect2, varscan2
- USP43 | c.2614C>A p.L872I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV53299463; called by muse, mutect2, varscan2
- VIRMA | c.1126T>C p.S376P | Missense Mutation (SNP) | VAF 99/291 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV52581204; called by muse, mutect2, varscan2
- VPS36 | c.124_126del p.L42del | In Frame Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs763216059; called by pindel, varscan2
- VSTM4 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs138812288; called by muse, mutect2, varscan2
- WDPCP | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55412000; called by muse, mutect2, varscan2
- WDR26 | c.2074G>A p.D692N (on ENST00000414423 / NM_001379403.1; = p.D592N on NM_025160.7) | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV54352720; called by muse, mutect2, varscan2
- XIRP1 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV61136626; called by muse, mutect2, varscan2
- XPA | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64304794; called by muse, mutect2, varscan2
- YTHDF1 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64832454; called by muse, mutect2, varscan2
- ZBTB34 | c.1298G>A p.C433Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59859242, COSV59859796; called by muse, mutect2, varscan2
- ZNF160 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.588); catalogued as rs747988442, COSV61998827; called by muse, mutect2, varscan2
- ZNF213 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV67727394; called by muse, mutect2, varscan2
- ZNF318 | c.4531G>A p.A1511T | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs931842314, COSV58929826; called by muse, mutect2, varscan2
- ZNF347 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 130/399 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs765677009, COSV61967447, COSV61969032; called by muse, mutect2, varscan2
- ZNF548 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60240114; called by muse, mutect2, varscan2
- ZNF569 | c.389dup p.S132Ffs*7 | Frame Shift Ins (INS) | VAF 43/166 reads (26%) | catalogued as rs752923644; called by mutect2, pindel, varscan2
- ZNF644 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV61345666; called by muse, mutect2, varscan2
- ZNF672 | c.1358A>C p.*453Sext*6 | Nonstop Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV60637114; called by muse, mutect2, varscan2
- ZNF782 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 184/720 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV56650905; called by muse, mutect2, varscan2
- ZNF79 | c.1417T>A p.Y473N | Missense Mutation (SNP) | VAF 136/335 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61070237; called by muse, mutect2, varscan2
- ZNF93 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as rs1162212499, COSV59373638; called by muse, mutect2, varscan2
- ZNFX1 | c.4253A>G p.H1418R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65593664; called by muse, mutect2
- ABCF1 | c.118del p.T40Rfs*8 | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | called by mutect2, pindel, varscan2
- ADAR | c.2628dup p.D877Rfs*3 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- ALCAM | c.958del p.S320Afs*2 | Frame Shift Del (DEL) | VAF 70/230 reads (30%) | called by mutect2, varscan2
- ANAPC1 | c.447del p.K149Nfs*16 | Frame Shift Del (DEL) | VAF 35/140 reads (25%) | called by mutect2, pindel, varscan2
- ARHGEF12 | c.3241_3245del p.K1081Efs*12 | Frame Shift Del (DEL) | VAF 68/225 reads (30%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.1463T>C p.V488A | Missense Mutation (SNP) | VAF 15/414 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2
- BAG4 | c.1365del p.G456Dfs*6 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- BOC | c.704del p.P235Qfs*47 | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- C3orf70 | c.674G>A p.W225* | Nonsense Mutation (SNP) | VAF 7/208 reads (3%) | called by muse, mutect2
- CA9 | c.1272del p.F424Lfs*12 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- CCAR2 | c.1729del p.E577Rfs*39 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- CCSAP | c.685del p.R229Gfs*21 | Frame Shift Del (DEL) | VAF 30/152 reads (20%) | called by mutect2, pindel, varscan2
- CDC27 | c.956del p.K319Sfs*24 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- CDK11B | c.110del p.N37Ifs*17 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- CLSTN2 | c.786dup p.D263Rfs*7 | Frame Shift Ins (INS) | VAF 48/152 reads (32%) | called by mutect2, pindel, varscan2
- CNTN2 | c.451del p.V151* | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- COL4A4 | c.1862del p.P621Qfs*32 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- CREB3L3 | c.738_739del p.K246Nfs*128 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- CUX2 | c.4286del p.P1429Lfs*23 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel
- CXCR3 | c.48del p.A17Pfs*33 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- DDX39B | c.447del p.F149Lfs*13 | Frame Shift Del (DEL) | VAF 47/148 reads (32%) | called by mutect2, varscan2
- FCGBP | c.6505C>T p.H2169Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- FMN2 | c.4243del p.I1415* | Frame Shift Del (DEL) | VAF 75/319 reads (24%) | called by mutect2, pindel, varscan2
- GPC4 | c.145dup p.L49Pfs*7 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- HPGDS | c.411del p.R138Efs*9 | Frame Shift Del (DEL) | VAF 230/832 reads (28%) | called by mutect2, pindel, varscan2
- IGF2R | c.4913_4915del p.F1638del | In Frame Del (DEL) | VAF 22/62 reads (35%) | called by pindel, varscan2
- INO80D | c.653_655del p.S218del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2
- INTU | c.1305del p.F435Lfs*33 | Frame Shift Del (DEL) | VAF 96/274 reads (35%) | called by mutect2, varscan2
- ITCH | c.475+3_475+6del p.X159_splice | Splice Site (DEL) | VAF 16/90 reads (18%) | called by pindel, varscan2
- KIF5C | c.2834del p.G945Efs*18 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- KLKB1 | c.125del p.P42Qfs*8 | Frame Shift Del (DEL) | VAF 46/145 reads (32%) | called by mutect2, pindel, varscan2
- KMT2D | c.5058del p.K1686Nfs*36 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- LRRN2 | c.1292del p.P431Qfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- MARK3 | c.792_793dup p.V265Efs*3 | Frame Shift Ins (INS) | VAF 16/85 reads (19%) | called by mutect2, varscan2
- MIS12 | c.159_160del p.C53* | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | called by pindel, varscan2
- MLH3 | c.2021del p.N674Ifs*6 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | called by mutect2, varscan2
- MORC2 | c.2042_2043del p.L681Rfs*54 (on ENST00000397641 / NM_001303256.3; = p.L619Rfs*54 on NM_014941.3) | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by pindel, varscan2
- MYOCD | c.684del p.S229Afs*4 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel
- NAV1 | c.3686del p.K1229Rfs*12 | Frame Shift Del (DEL) | VAF 81/384 reads (21%) | called by mutect2, pindel, varscan2
- NCBP1 | c.392del p.L131Yfs*5 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
- NFX1 | c.2414del p.G805Afs*75 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- NOMO1 | c.3305del p.P1102Hfs*42 | Frame Shift Del (DEL) | VAF 122/506 reads (24%) | called by pindel, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 51/154 reads (33%) | called by mutect2, pindel, varscan2
- OR2Y1 | c.751dup p.Y251Lfs*17 | Frame Shift Ins (INS) | VAF 119/474 reads (25%) | called by mutect2, pindel, varscan2
- OR4F17 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 40/1382 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCNX2 | c.4168del p.Y1390Mfs*4 | Frame Shift Del (DEL) | VAF 31/135 reads (23%) | called by mutect2, pindel, varscan2
- PIEZO2 | c.8251dup p.T2751Nfs*? | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.2815del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- PYGL | c.2190del p.E731Nfs*9 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | called by mutect2, pindel, varscan2
- RAE1 | c.743del p.P248Rfs*29 | Frame Shift Del (DEL) | VAF 76/244 reads (31%) | called by mutect2, pindel, varscan2
- RAMP2 | c.168del p.X56_splice | Splice Site (DEL) | VAF 35/101 reads (35%) | called by mutect2, pindel, varscan2
- RBM15B | c.2236del p.V746* | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- RECK | c.2316_2317dup p.A773Vfs*61 | Frame Shift Ins (INS) | VAF 19/55 reads (35%) | called by mutect2, varscan2
- SCAF11 | c.2558del p.K853Rfs*46 | Frame Shift Del (DEL) | VAF 138/442 reads (31%) | called by mutect2, varscan2
- SENP6 | c.2590del p.I864* | Frame Shift Del (DEL) | VAF 79/281 reads (28%) | called by mutect2, pindel, varscan2
- SERHL2 | c.582_584del p.L195del | In Frame Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- SH2B1 | c.1423del p.R475Afs*68 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel, varscan2
- SLC26A8 | c.2525del p.N842Mfs*2 | Frame Shift Del (DEL) | VAF 91/251 reads (36%) | called by mutect2, varscan2
- STAU2 | c.1494del p.K498Nfs*6 (on ENST00000524300 / NM_001164380.2; = p.K466Nfs*6 on NM_014393.2) | Frame Shift Del (DEL) | VAF 31/205 reads (15%) | called by mutect2, pindel, varscan2
- TAF5 | c.721del p.Y241Ifs*11 | Frame Shift Del (DEL) | VAF 31/150 reads (21%) | called by mutect2, pindel, varscan2
- TAFA3 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2
- TBC1D2B | c.1168del p.V390Sfs*37 | Frame Shift Del (DEL) | VAF 58/167 reads (35%) | called by mutect2, pindel, varscan2
- TENM1 | c.6148dup p.S2050Kfs*8 | Frame Shift Ins (INS) | VAF 70/225 reads (31%) | called by mutect2, pindel, varscan2
- TMEM192 | c.200del p.L67* | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | called by mutect2, pindel, varscan2
- TMEM92 | c.413del p.P138Lfs*86 | Frame Shift Del (DEL) | VAF 97/320 reads (30%) | called by mutect2, pindel, varscan2
- TRPC3 | c.422dup p.N141Kfs*72 (on ENST00000379645 / NM_001366479.2; = p.N68Kfs*72 on NM_003305.2) | Frame Shift Ins (INS) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- USP1 | c.1985dup p.N662Kfs*18 | Frame Shift Ins (INS) | VAF 56/164 reads (34%) | called by mutect2, varscan2
- USP10 | c.1818del p.F606Lfs*64 | Frame Shift Del (DEL) | VAF 47/173 reads (27%) | called by mutect2, pindel, varscan2
- ZMYM6 | c.292del p.M98Cfs*49 | Frame Shift Del (DEL) | VAF 47/240 reads (20%) | called by mutect2, varscan2
- ZNF358 | c.394del p.Q132Rfs*35 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel
- ZNF502 | c.174del p.K58Nfs*7 | Frame Shift Del (DEL) | VAF 49/176 reads (28%) | called by mutect2, pindel, varscan2
- ZNF804A | c.1059dup p.E354* | Frame Shift Ins (INS) | VAF 31/181 reads (17%) | called by mutect2, pindel, varscan2
- AC005324.2 | c.174G>A p.Q58= | Silent (SNP) | VAF 136/388 reads (35%) | catalogued as COSV60885448; called by muse, mutect2, varscan2
- AC008397.2 | c.1200G>A p.T400= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs568953481, COSV53204324; called by muse, mutect2, varscan2
- AC090517.4 | c.1548T>G p.A516= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV50995648; called by muse, mutect2, varscan2
- ACTA1 | c.15C>T p.D5= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs1397255499, COSV100796794, COSV64202815; called by muse, varscan2
- ACTG2 | c.1053C>T p.S351= | Silent (SNP) | VAF 13/246 reads (5%) | catalogued as rs1366480931, COSV100609169; called by muse, mutect2
- ADAM32 | c.687T>A p.V229= | Silent (SNP) | VAF 10/302 reads (3%) | catalogued as COSV101165396, COSV65954450; called by muse, mutect2
- ADAMTS16 | c.2475C>T p.P825= | Silent (SNP) | VAF 79/231 reads (34%) | catalogued as rs749043144, COSV56976070; called by muse, mutect2, varscan2
- AGFG2 | c.1116C>A p.A372= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV53543823, COSV53544646; called by muse, mutect2, varscan2
- ALDH1A1 | c.288C>T p.I96= | Silent (SNP) | VAF 76/207 reads (37%) | catalogued as rs376026961; called by muse, mutect2, varscan2
- ALDH3A2 | c.1266G>A p.Q422= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV51565409; called by muse, mutect2, varscan2
- ALPK2 | c.3891T>C p.A1297= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as COSV64489759; called by muse, mutect2, varscan2
- AP3D1 | c.1296G>A p.R432= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV61424078; called by muse, mutect2, varscan2
- ARHGAP33 | c.1026C>T p.H342= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs374408368; called by muse, mutect2, varscan2
- ATF7IP2 | c.1689A>G p.L563= | Silent (SNP) | VAF 12/363 reads (3%) | catalogued as rs1431782928, COSV100202617; called by muse, mutect2
- BCOR | c.1551C>T p.N517= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs1325290935, COSV60698383; called by muse, mutect2, varscan2
- BPTF | c.2109C>T p.I703= | Silent (SNP) | VAF 110/305 reads (36%) | catalogued as COSV58830562; called by muse, mutect2, varscan2
- BTBD17 | c.258G>A p.L86= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1270310595, COSV64730836; called by muse, mutect2
- CA12 | c.945C>T p.G315= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs766120265, COSV51603931; called by muse, mutect2, varscan2
- CABIN1 | c.2763G>A p.Q921= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54076920; called by muse, mutect2, varscan2
- CAMSAP2 | c.3756T>C p.I1252= (on ENST00000236925 / NM_001297707.2; = p.I1241= on NM_203459.3) | Silent (SNP) | VAF 55/241 reads (23%) | catalogued as COSV52666343; called by muse, mutect2, varscan2
- CANT1 | c.1101C>T p.S367= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs773042538, COSV56604807; called by muse, mutect2, varscan2
- CAPN11 | c.1302C>T p.D434= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs369599500; called by muse, mutect2, varscan2
- CCDC12 | c.390G>T p.R130= (on ENST00000425441 / NM_001277074.1; = p.R143= on NM_144716.5) | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV52764875; called by muse, mutect2, varscan2
- CDK5R2 | c.867C>T p.D289= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs1251248489, COSV56935408; called by muse, mutect2, varscan2
- CEP192 | c.3528C>T p.S1176= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV100381206; called by muse, mutect2
- CHAC1 | c.609C>T p.D203= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs750093950, COSV71435895; called by muse, mutect2, varscan2
- CLSTN1 | c.1134G>A p.V378= (on ENST00000377298 / NM_001009566.3; = p.V368= on NM_014944.4) | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV63646259; called by muse, mutect2, varscan2
- CNST | c.2106C>T p.D702= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV63622790; called by muse, mutect2, varscan2
- CRYBG1 | c.3351C>T p.S1117= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs374531349, COSV64810270; called by muse, mutect2, varscan2
- CSF2RA | c.666C>T p.S222= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as rs746955662, COSV62623301; called by muse, mutect2, varscan2
- DDX39A | c.777C>T p.H259= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs556046710, COSV54390315; called by muse, mutect2, varscan2
- DHX8 | c.3360G>A p.P1120= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs1292588107, COSV52250631; called by muse, mutect2, varscan2
- DOCK3 | c.4857C>T p.F1619= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs758252356, COSV56500204; called by muse, mutect2, varscan2
- EEF2K | c.123C>A p.P41= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV53778074; called by muse, mutect2, varscan2
- FAM160A2 | c.888C>A p.A296= | Silent (SNP) | VAF 142/378 reads (38%) | catalogued as COSV56409252; called by muse, mutect2, varscan2
- FAM71B | c.576C>T p.D192= | Silent (SNP) | VAF 14/426 reads (3%) | catalogued as rs1007941618, COSV57228977, COSV57229114; called by muse, mutect2
- FANCD2 | c.2454C>T p.H818= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV55031793; called by muse, mutect2, varscan2
- FBN3 | c.3570C>T p.D1190= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs757038263, COSV54452353; called by muse, mutect2, varscan2
- FEM1A | c.1803C>T p.I601= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV54162822; called by muse, mutect2, varscan2
- FN1 | c.2538G>A p.S846= | Silent (SNP) | VAF 102/272 reads (38%) | catalogued as rs145300210; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRYL | c.5571G>A p.G1857= | Silent (SNP) | VAF 54/166 reads (33%) | catalogued as COSV51937878, COSV99976896; called by muse, mutect2, varscan2
- GAA | c.783C>T p.A261= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs757356178, COSV56406551; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAREM1 | c.2391C>T p.G797= (on ENST00000269209 / NM_001242409.2; = p.G796= on NM_022751.3) | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs775831845, COSV52505288; called by muse, mutect2, varscan2
- GEMIN5 | c.207C>T p.G69= | Silent (SNP) | VAF 57/143 reads (40%) | catalogued as COSV53557718; called by muse, mutect2, varscan2
- GMPPA | c.1056C>T p.R352= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs930036563, COSV58005903; called by muse, mutect2, varscan2
- GPR15 | c.456A>G p.V152= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV52519904; called by muse, mutect2, varscan2
- GRIK5 | c.2499A>G p.S833= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV53474181; called by muse, mutect2, varscan2
- GRM7 | c.1209G>A p.E403= | Silent (SNP) | VAF 62/207 reads (30%) | catalogued as COSV63126931; called by muse, mutect2, varscan2
- HDGF | c.459G>A p.A153= | Silent (SNP) | VAF 105/360 reads (29%) | catalogued as rs201820242, COSV61975412; called by muse, mutect2, varscan2
- HTR3A | c.517C>T p.L173= | Silent (SNP) | VAF 109/307 reads (36%) | catalogued as COSV55467679, COSV55470780; called by muse, mutect2, varscan2
- IFT140 | c.36G>A p.P12= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as rs574028286, COSV68485692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGLV6-57 | c.114C>A p.T38= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs577188552, COSV66503928; called by muse, mutect2, varscan2
- INKA1 | c.348A>G p.A116= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- KCND2 | c.327C>T p.H109= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as rs764237787, COSV100478320, COSV58567402; called by muse, mutect2, varscan2
- KCNJ2 | c.207C>T p.L69= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs1007358932, COSV54659963; called by muse, mutect2, varscan2
- KDM5C | c.2193T>C p.L731= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV100949146; called by muse, mutect2
- KIF17 | c.2058G>A p.V686= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV56115250; called by muse, mutect2, varscan2
- KMT2D | c.7572G>A p.T2524= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs772878105, COSV56407215, COSV56474781; ClinVar: benign; called by muse, mutect2
- KRT20 | c.264G>A p.V88= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV51423819; called by muse, mutect2, varscan2
- LDHAL6B | c.102G>A p.T34= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs1323762963, COSV55681933; called by muse, mutect2, varscan2
- LENG8 | c.1323C>T p.S441= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs199822118, COSV58725780; called by muse, mutect2, varscan2
- LONP1 | c.2439C>T p.S813= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs368187848; called by muse, mutect2, varscan2
- LRRC15 | c.1674C>T p.C558= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs200049182; called by muse, mutect2, varscan2
- LTBP2 | c.4920C>T p.R1640= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56204288; called by muse, mutect2, varscan2
- MASTL | c.1413C>T p.N471= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as rs746095581, COSV60909224; called by muse, mutect2, varscan2
- MCC | c.2376G>A p.S792= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as rs142331664; called by muse, mutect2, varscan2
- MDGA1 | c.2631G>A p.Q877= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV51791230; called by muse, mutect2, varscan2
- MSMP | c.222C>T p.G74= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1243695269, COSV100960214, COSV65238740; called by mutect2, varscan2
- MYH13 | c.5056C>T p.L1686= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52819860; called by muse, mutect2, varscan2
- MYO7B | c.819C>T p.G273= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs752535821, COSV67344084; called by muse, mutect2
- NAA16 | c.2271C>T p.N757= | Silent (SNP) | VAF 118/328 reads (36%) | catalogued as rs759568986, COSV65127279; called by muse, mutect2, varscan2
- NAB2 | c.468C>T p.R156= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs752673093, COSV55665315; called by muse, mutect2, varscan2
- NCOA6 | c.792G>A p.Q264= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs772784924, COSV62860937; called by muse, mutect2, varscan2
- NREP | c.135C>T p.N45= | Silent (SNP) | VAF 80/218 reads (37%) | catalogued as rs546555506, COSV57404545; called by muse, mutect2, varscan2
- NRN1 | c.351G>A p.A117= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs760207074, COSV55204888; called by muse, mutect2, varscan2
- NTRK3 | c.1590G>A p.V530= | Silent (SNP) | VAF 101/278 reads (36%) | catalogued as rs1479298642, COSV62294311; called by muse, mutect2, varscan2
- OR9I1 | c.585C>T p.I195= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as rs1027806962, COSV56925165; called by muse, mutect2, varscan2
- PCDHA3 | c.1287C>T p.D429= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV63543404; called by muse, mutect2
- PCDHB15 | c.1659C>T p.D553= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV50858046; called by muse, mutect2, varscan2
- PCDHB7 | c.849C>T p.Y283= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV50753492; called by muse, mutect2, varscan2
- PCDHGA8 | c.1560C>T p.F520= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV53891998; called by muse, mutect2, varscan2
- PILRB | c.681C>T p.F227= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV60332984; called by muse, mutect2, varscan2
- PLXNB1 | c.3846G>A p.T1282= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs761842270, COSV56486278; called by muse, mutect2, varscan2
- PNRC1 | c.681T>A p.S227= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV60138873; called by muse, mutect2, varscan2
- POM121L12 | c.639G>A p.R213= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV68692121; called by muse, mutect2, varscan2
- POSTN | c.1467C>T p.R489= | Silent (SNP) | VAF 97/310 reads (31%) | catalogued as rs1234284132, COSV65711689; called by muse, mutect2, varscan2
- RAPGEF2 | c.3207C>T p.P1069= | Silent (SNP) | VAF 64/187 reads (34%) | catalogued as rs376475495; called by muse, mutect2, varscan2
- RAPGEF6 | c.4770C>T p.S1590= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs771222054, COSV57239288; called by muse, mutect2, varscan2
- RBM10 | c.996C>T p.R332= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV61307533; called by muse, mutect2, varscan2
- RBM47 | c.259C>T p.L87= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55929650; called by muse, mutect2, varscan2
- RIPOR3 | c.1491C>T p.H497= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs545997871, COSV50385519; called by muse, mutect2, varscan2
- RNF213 | c.11232G>A p.Q3744= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV60388605; called by muse, mutect2, varscan2
- ROM1 | c.861G>A p.R287= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs748278937, COSV53881203; called by muse, mutect2, varscan2
- RSPO3 | c.795G>A p.S265= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as rs757866402, COSV63149288; called by muse, mutect2, varscan2
- RYR2 | c.14316C>A p.G4772= | Silent (SNP) | VAF 24/457 reads (5%) | catalogued as COSV100770053; called by muse, mutect2
- SEMA3B | c.1008C>T p.G336= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV60350804; called by muse, mutect2, varscan2
- SEPHS1 | c.729C>T p.N243= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as COSV59256904; called by muse, mutect2, varscan2
- SFMBT2 | c.1878C>T p.C626= | Silent (SNP) | VAF 53/199 reads (27%) | catalogued as COSV62804522; called by muse, mutect2, varscan2
- SIPA1L3 | c.2727C>T p.F909= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV55908112; called by muse, mutect2, varscan2
- SLC24A4 | c.927C>T p.D309= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs762780369, COSV54106502; called by muse, mutect2, varscan2
- SLC41A2 | c.1299T>C p.S433= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV51601608; called by muse, mutect2, varscan2
- SLC44A1 | c.600C>T p.V200= | Silent (SNP) | VAF 81/256 reads (32%) | catalogued as COSV58261837; called by muse, mutect2, varscan2
- SLFN11 | c.1611G>A p.A537= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs748805736, COSV57697250; called by muse, mutect2, varscan2
- SLIT3 | c.331C>T p.L111= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as rs1251735498, COSV60590488; called by muse, mutect2, varscan2
- SPATA7 | c.978C>T p.D326= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as rs1180396790, COSV50415812; called by muse, mutect2, varscan2
- SPEG | c.3573G>A p.L1191= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV56662152; called by muse, mutect2, varscan2
- SSTR4 | c.363G>A p.A121= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1280577576, COSV54796667; called by muse, mutect2, varscan2
- STS | c.1407C>T p.N469= | Silent (SNP) | VAF 71/242 reads (29%) | catalogued as COSV54265343; called by muse, mutect2, varscan2
- TACR1 | c.72G>A p.Q24= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV59478849; called by muse, mutect2, varscan2
- TBC1D9 | c.3474C>T p.D1158= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs763025261, COSV71306706; called by muse, mutect2, varscan2
- TCF20 | c.2940G>A p.P980= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs374547518; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCF7L2 | c.636G>A p.T212= (on ENST00000355995 / NM_001367943.1; = p.T189= on NM_030756.5) | Silent (SNP) | VAF 78/262 reads (30%) | catalogued as rs747875356, COSV53335725; called by muse, mutect2, varscan2
- TCHH | c.4212C>T p.R1404= | Silent (SNP) | VAF 152/498 reads (31%) | catalogued as rs375272944, COSV64272321; called by muse, mutect2, varscan2
- THAP11 | c.433C>T p.L145= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs770610641, COSV54645026; called by muse, mutect2, varscan2
- TIA1 | c.504T>A p.G168= (on ENST00000433529 / NM_001351511.1; = p.G157= on NM_022037.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as COSV57005434, COSV57008907; called by muse, mutect2, varscan2
- TNKS | c.3966C>T p.A1322= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs370002383; called by muse, mutect2, varscan2
- TNN | c.1950C>T p.Y650= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as rs759866598, COSV53420837; called by muse, mutect2, varscan2
- TRIP13 | c.748C>T p.L250= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV51319175; called by muse, mutect2, varscan2
- TRPM2 | c.4044G>A p.L1348= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV55965122; called by muse, mutect2, varscan2
- TTI1 | c.2571A>G p.P857= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs781292911, COSV65060256; called by muse, mutect2, varscan2
- VPS13C | c.4572T>C p.H1524= (on ENST00000644861 / NM_020821.3; = p.H1481= on NM_017684.5) | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV51119918; called by muse, mutect2
- WDR83OS | c.63G>A p.P21= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV54417152, COSV54419746; called by muse, mutect2, varscan2
- WNK1 | c.6933C>T p.T2311= (on ENST00000315939 / NM_018979.4; = p.T2063= on NM_014823.3) | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV57272085; called by muse, mutect2, varscan2
- ZBTB33 | c.477T>C p.N159= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV100434173; called by muse, mutect2
- ZNF182 | c.471C>T p.P157= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as rs782514467, COSV59355643; called by muse, mutect2, varscan2
- ZNF444 | c.351G>A p.V117= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV61362733; called by muse, mutect2, varscan2
- ZNF555 | c.1398C>T p.C466= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV62072680; called by muse, mutect2, varscan2
- ZNF578 | c.1410T>C p.L470= | Silent (SNP) | VAF 11/247 reads (4%) | catalogued as COSV101405049; called by muse, mutect2
- ZNF616 | c.2103T>C p.S701= | Silent (SNP) | VAF 100/331 reads (30%) | catalogued as COSV57509278; called by muse, mutect2, varscan2
- AL590867.2 | n.103G>A | RNA (SNP) | VAF 58/201 reads (29%) | called by muse, mutect2, varscan2
- AQR | c.472-1024G>A | Intron (SNP) | VAF 88/328 reads (27%) | catalogued as rs562162245; called by muse, mutect2, varscan2
- ARMC8 | c.1134+51A>G | Intron (SNP) | VAF 13/46 reads (28%) | catalogued as COSV61767516; called by muse, mutect2, varscan2
- CLCN5 | c.17-33861C>A | Intron (SNP) | VAF 160/426 reads (38%) | catalogued as COSV65799955; called by muse, mutect2, varscan2
- FBXW7 | c.501+29113G>A | Intron (SNP) | VAF 47/144 reads (33%) | catalogued as rs200475902; called by muse, mutect2, varscan2
- MCF2L | c.369-581C>T | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs565211788, COSV65050622; called by muse, varscan2
- MFSD4B | c.*186del | 3'UTR (DEL) | VAF 35/106 reads (33%) | catalogued as rs540972233; called by mutect2, varscan2
- NCL | c.1832+126C>T | Intron (SNP) | VAF 57/143 reads (40%) | catalogued as rs200830899; called by muse, mutect2, varscan2
- NRXN1 | c.832+1865T>A | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as COSV67999538; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791015 G>A | 5'Flank (SNP) | VAF 35/80 reads (44%) | catalogued as rs778417990; called by muse, mutect2, varscan2
- SNORD115-41 | n.78G>A | RNA (SNP) | VAF 31/135 reads (23%) | catalogued as rs567966464; called by muse, mutect2, varscan2
- SPATA1 | c.-48del | 5'UTR (DEL) | VAF 5/20 reads (25%) | catalogued as rs1045281118; called by mutect2, varscan2
- TBX5 | c.982+9G>A | Intron (SNP) | VAF 69/242 reads (29%) | catalogued as rs1380679745, COSV59858164; called by muse, mutect2, varscan2
- WIPI2 | c.212-178G>A | Intron (SNP) | VAF 13/44 reads (30%) | catalogued as rs765784182, COSV56586690; called by muse, mutect2, varscan2
